Somatic mutation profile of cancer-model specimen HCM-CSHL-0320-C02-85A (3D Organoid, passage 6; aliquot HCM-CSHL-0320-C02-85A-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0320-C02, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX.
Specimen HCM-CSHL-0320-C02-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75f8c4ea-f82f-490a-b2a5-bbda13cdeb2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0320-C02-10A (Blood Derived Normal), aliquot HCM-CSHL-0320-C02-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5e45e02-1674-408a-ad14-1717f0c0c430

The open-access MAF lists 105 somatic variants for this specimen: 75 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 28, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 1, Splice Region 1, RNA 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 142/230 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111033174, CM050717, COSV68683457; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANTKMT | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1390893042; called by muse, mutect2
- AP3B2 | c.2593C>T p.R865W (on ENST00000261722; = p.R859W on NM_004644.5) | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.99); catalogued as rs201234574, COSV55607570; called by muse, mutect2, varscan2
- ARHGAP25 | c.1255C>T p.P419S (on ENST00000409202 / NM_001007231.3; = p.P411S on NM_014882.3) | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.021); catalogued as COSV54901269; called by muse, mutect2
- BCL9L | c.3925G>A p.E1309K | Missense Mutation (SNP) | VAF 214/604 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs199836573; called by muse, mutect2, varscan2
- CCDC136 | c.18G>T p.G6= | Splice Region (SNP) | VAF 106/223 reads (48%) | catalogued as COSV52798524; called by muse, mutect2, varscan2
- CSMD1 | c.6977G>A p.R2326Q (on ENST00000520002; = p.R2325Q on NM_033225.6) | Missense Mutation (SNP) | VAF 86/86 reads (100%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.928); catalogued as rs201233859; called by muse, mutect2, varscan2
- CTCF | c.953-1G>T p.X318_splice | Splice Site (SNP) | VAF 153/316 reads (48%) | catalogued as COSV50469722; called by muse, mutect2, varscan2
- FUT4 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 140/453 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs201757138, COSV100708064, COSV100708209; called by muse, mutect2, varscan2
- HRNR | c.5630G>C p.S1877T | Missense Mutation (SNP) | VAF 108/3714 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1553201832; called by muse, mutect2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 221/773 reads (29%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KCND2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 208/433 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs972799571; called by muse, mutect2, varscan2
- KRTAP13-2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs774589922, COSV67762013; called by muse, mutect2, varscan2
- MYO3A | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1490857808, COSV56319355; called by muse, mutect2, varscan2
- NFE2L2 | c.95T>A p.V32E | Missense Mutation (SNP) | VAF 157/311 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV67960747, COSV67960841; called by muse, mutect2, varscan2
- NOD1 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 266/482 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs776642674, COSV56114041; called by muse, mutect2, varscan2
- NT5DC3 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750672309; called by muse, mutect2, varscan2
- NWD1 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 145/555 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as rs150409927; called by muse, mutect2
- P2RX3 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54441543; called by muse, mutect2, varscan2
- POTEC | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 168/439 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs745334772, COSV62801091; called by muse, mutect2, varscan2
- SEMA5B | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 870/1270 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs1239279646; called by muse, mutect2, varscan2
- SLC8A3 | c.2562C>G p.F854L (on ENST00000381269 / NM_183002.3; = p.F852L on NM_033262.4) | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53687727; called by muse, mutect2
- SPATA16 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 407/574 reads (71%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100651228; called by muse, mutect2, varscan2
- STRN3 | c.1399C>T p.R467* (on ENST00000357479 / NM_001083893.2; = p.R383* on NM_014574.4) | Nonsense Mutation (SNP) | VAF 141/284 reads (50%) | catalogued as rs1325547219, COSV62579369; called by muse, mutect2, varscan2
- SYCP2L | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 112/175 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV51652975; called by muse, mutect2, varscan2
- TBC1D10B | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 354/598 reads (59%) | catalogued as rs1277558423; called by muse, mutect2, varscan2
- UNC5B | c.2065C>G p.R689G | Missense Mutation (SNP) | VAF 127/408 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as COSV100100229, COSV58982240; called by muse, mutect2, varscan2
- USH2A | c.12560G>A p.R4187H | Missense Mutation (SNP) | VAF 228/328 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs147304271, CM1410607; called by muse, mutect2, varscan2
- VCAN | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 119/196 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs540758500, COSV54115974; called by muse, mutect2, varscan2
- ZNF518A | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV100283704; called by muse, mutect2, varscan2
- ABCA7 | c.6294G>T p.L2098F | Missense Mutation (SNP) | VAF 196/306 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ACSM2A | c.1094A>C p.E365A (on ENST00000219054; = p.E286A on NM_001308169.2) | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL1 | c.2415_2418del p.T806Ffs*11 | Frame Shift Del (DEL) | VAF 112/300 reads (37%) | called by mutect2, pindel, varscan2
- C5orf38 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 203/456 reads (45%) | called by muse, mutect2, varscan2
- CAMKK1 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBFA2T2 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC33 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 148/257 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CNTLN | c.3342T>A p.N1114K | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CUX1 | c.3422A>G p.D1141G | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCXR | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 307/658 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLK1 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 108/520 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH6 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.11627G>C p.R3876T | Missense Mutation (SNP) | VAF 99/185 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIP1 | c.2681C>T p.A894V (on ENST00000359742 / NM_001379345.1; = p.A842V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/394 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- GUCY1B1 | c.485T>C p.I162T | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GXYLT1 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- IMPG2 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 58/656 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- IVNS1ABP | c.251_258dup p.L87Kfs*4 | Frame Shift Ins (INS) | VAF 76/230 reads (33%) | called by mutect2, varscan2
- JAK3 | c.1071C>G p.H357Q | Missense Mutation (SNP) | VAF 148/552 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- KIAA0319 | c.2627C>A p.P876H | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMB2 | c.2684G>A p.G895D | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LMTK2 | c.1911T>G p.N637K | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MDM2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED13L | c.4526A>G p.H1509R | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MMP20 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MTREX | c.693T>G p.I231M | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.21353C>T p.T7118I | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); called by muse, mutect2
- MYLK3 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 272/460 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NCOA2 | c.1585T>C p.Y529H | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NMT2 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 109/178 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2A4 | c.289A>T p.M97L | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARP8 | c.2468A>G p.E823G | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDHA6 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 53/437 reads (12%) | called by muse, mutect2, varscan2
- RC3H2 | c.1504_1505del p.S502Cfs*8 | Frame Shift Del (DEL) | VAF 143/382 reads (37%) | called by mutect2, pindel, varscan2
- SLC30A5 | c.2253_2254del p.Q751Hfs*17 | Frame Shift Del (DEL) | VAF 52/248 reads (21%) | called by mutect2, pindel, varscan2
- SYT13 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 129/214 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TADA2A | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TMEM106B | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 151/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.836_848del p.G279Afs*62 | Frame Shift Del (DEL) | VAF 317/332 reads (95%) | called by mutect2, pindel, varscan2
- TRAV36DV7 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- VCAN | c.9892C>A p.Q3298K | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13C | c.7526G>A p.G2509E (on ENST00000644861 / NM_020821.3; = p.G2466E on NM_017684.5) | Missense Mutation (SNP) | VAF 152/256 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ZNF208 | c.1031A>C p.K344T | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ZNF606 | c.1482C>G p.N494K | Missense Mutation (SNP) | VAF 90/542 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF644 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 115/243 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AQP8 | c.486C>T p.I162= | Silent (SNP) | VAF 232/429 reads (54%) | catalogued as COSV54846507; called by muse, mutect2, varscan2
- DYSF | c.4302G>A p.S1434= | Silent (SNP) | VAF 207/386 reads (54%) | catalogued as rs368451006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FABP4 | c.354C>T p.C118= | Silent (SNP) | VAF 54/226 reads (24%) | catalogued as rs372210964; called by muse, mutect2, varscan2
- FAM120C | c.405G>A p.T135= | Silent (SNP) | VAF 19/402 reads (5%) | called by muse, mutect2
- FOXG1 | c.234G>A p.P78= | Silent (SNP) | VAF 66/106 reads (62%) | catalogued as rs1249389474; called by muse, varscan2
- GREB1 | c.1545C>T p.S515= | Silent (SNP) | VAF 196/806 reads (24%) | catalogued as COSV52185733; called by muse, mutect2, varscan2
- IGKJ4 | c.12C>T p.G4= | Silent (SNP) | VAF 174/340 reads (51%) | catalogued as rs181159708; called by muse, mutect2, varscan2
- L3MBTL4 | c.1530G>A p.V510= | Silent (SNP) | VAF 120/511 reads (23%) | called by muse, mutect2, varscan2
- LAMTOR4 | c.171C>T p.R57= | Silent (SNP) | VAF 322/622 reads (52%) | catalogued as rs1163588756, COSV57586930; called by muse, mutect2, varscan2
- MUC16 | c.16128C>A p.T5376= | Silent (SNP) | VAF 114/344 reads (33%) | called by muse, mutect2, varscan2
- NCAM1 | c.1821A>T p.P607= (on ENST00000316851 / NM_181351.5; = p.P597= on NM_000615.7) | Silent (SNP) | VAF 64/206 reads (31%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3084C>A p.S1028= | Silent (SNP) | VAF 92/398 reads (23%) | called by muse, mutect2, varscan2
- NCOR2 | c.4764G>A p.T1588= | Silent (SNP) | VAF 217/449 reads (48%) | catalogued as rs571877591, COSV62297140; called by muse, mutect2, varscan2
- NEURL4 | c.3312C>T p.T1104= | Silent (SNP) | VAF 226/510 reads (44%) | catalogued as rs762261141; called by muse, mutect2, varscan2
- NLRP14 | c.561T>G p.V187= | Silent (SNP) | VAF 113/226 reads (50%) | called by muse, mutect2, varscan2
- NUMA1 | c.4869C>T p.A1623= | Silent (SNP) | VAF 152/227 reads (67%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1566G>A p.P522= | Silent (SNP) | VAF 256/701 reads (37%) | catalogued as COSV56518249; called by muse, mutect2, varscan2
- PGM2L1 | c.645T>C p.G215= | Silent (SNP) | VAF 81/273 reads (30%) | called by muse, mutect2, varscan2
- PRR23A | c.249G>A p.P83= | Silent (SNP) | VAF 110/818 reads (13%) | catalogued as rs1463186452, COSV67215544; called by muse, mutect2, varscan2
- RBP4 | c.120G>A p.G40= | Silent (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- SETD1B | c.5196G>A p.K1732= | Silent (SNP) | VAF 186/375 reads (50%) | called by muse, mutect2, varscan2
- SLC7A7 | c.1197T>C p.G399= | Silent (SNP) | VAF 96/506 reads (19%) | called by muse, mutect2, varscan2
- SMPDL3B | c.708C>T p.H236= | Silent (SNP) | VAF 79/175 reads (45%) | catalogued as rs752394375, COSV65855073; called by muse, mutect2, varscan2
- TDRD5 | c.432G>A p.A144= | Silent (SNP) | VAF 96/549 reads (17%) | catalogued as rs369571297; called by muse, varscan2
- THADA | c.2484C>A p.G828= | Silent (SNP) | VAF 150/313 reads (48%) | called by muse, mutect2, varscan2
- TRIML1 | c.771C>G p.L257= | Silent (SNP) | VAF 143/143 reads (100%) | catalogued as rs759560264, COSV60194686; called by muse, mutect2, varscan2
- UGGT2 | c.2655A>G p.E885= | Silent (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- ZNF571 | c.222G>A p.G74= | Silent (SNP) | VAF 94/272 reads (35%) | catalogued as rs1242749613; called by muse, varscan2
- AC011475.1 | chr19:10602543 C>A | 5'Flank (SNP) | VAF 236/431 reads (55%) | catalogued as rs535107339; called by muse, mutect2, varscan2
- NPAP1L | n.681G>A | RNA (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
